Somatic mutation profile of tumor specimen TCGA-C5-A2LX-01A (aliquot TCGA-C5-A2LX-01A-11D-A18J-09) from TCGA case TCGA-C5-A2LX, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 54.9 years (20,070 days).
Specimen TCGA-C5-A2LX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1b7b16a-bd02-4c72-8537-b8cc88da6944.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A2LX-10A (Blood Derived Normal), aliquot TCGA-C5-A2LX-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffe7ec28-1459-4949-8b09-fb918daddd20

The open-access MAF lists 211 somatic variants for this specimen: 155 protein-altering or splice-affecting, 48 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 48, Nonsense Mutation 11, RNA 3, Frame Shift Del 3, Intron 3, Splice Site 3, Splice Region 2, Translation Start Site 1, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.7238T>A p.L2413Q (on ENST00000272895 / NM_173076.3; = p.L2095Q on NM_015657.3) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55967748; called by muse, mutect2, varscan2
- ABCA13 | c.14740C>A p.H4914N | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68949041; called by muse, mutect2, varscan2
- ABCA4 | c.5866G>T p.D1956Y | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64675579; called by muse, mutect2, varscan2
- ABCB9 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770574958, COSV54893148; called by muse, mutect2, varscan2
- ADAM20 | c.2050G>A p.G684R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as rs758796268, COSV56455698; called by muse, mutect2, varscan2
- ADAMTS7 | c.1955C>T p.T652I | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV66308562; called by muse, mutect2, varscan2
- ADGRV1 | c.5690C>T p.S1897F | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67990529; called by muse, mutect2, varscan2
- ADGRV1 | c.11887G>T p.G3963C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV67990533; called by muse, mutect2, varscan2
- AFP | c.936A>T p.Q312H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs753006750, COSV56926170; called by muse, mutect2, varscan2
- AMD1 | c.146G>C p.C49S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64387818; called by muse, mutect2, varscan2
- APIP | c.150G>C p.L50F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV53507800; called by muse, mutect2, varscan2
- ARID5B | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs140010870, COSV54425577; called by muse, mutect2, varscan2
- ATF2 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 15/79 reads (19%) | catalogued as COSV51371721; called by muse, mutect2, varscan2
- B3GNT5 | c.145A>T p.R49* | Nonsense Mutation (SNP) | VAF 16/108 reads (15%) | catalogued as COSV58476502; called by muse, mutect2, varscan2
- BAAT | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as rs988137993, COSV52290107; called by muse, mutect2, varscan2
- BCAP31 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 54/79 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV61452102; called by muse, mutect2, varscan2
- CACNB4 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1023200310, COSV52390628; called by muse, mutect2, varscan2
- CCDC47 | c.342C>G p.S114R | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.104); catalogued as COSV56723938, COSV56724160; called by muse, mutect2, varscan2
- CDK13 | c.2841C>G p.F947L | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV51698598, COSV99475488; called by muse, mutect2
- CEP104 | c.1908G>T p.M636I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV65518410; called by muse, mutect2, varscan2
- CERCAM | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65711509; called by muse, mutect2, varscan2
- CFAP77 | c.365G>C p.G122A | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58013846; called by muse, mutect2, varscan2
- CFAP97 | c.776C>G p.S259* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs765649140, COSV57111398; called by muse, mutect2, varscan2
- CHD4 | c.4846G>A p.E1616K (on ENST00000357008 / NM_001363606.2; = p.E1629K on NM_001273.5) | Missense Mutation (SNP) | VAF 75/139 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs760270237, COSV58906182; called by muse, mutect2, varscan2
- COL11A1 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.079); catalogued as COSV62190046; called by muse, mutect2, varscan2
- CPAMD8 | c.2068G>A p.D690N (on ENST00000651564; = p.D643N on NM_015692.5) | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV104394330, COSV52237125; called by muse, mutect2, varscan2
- CREBBP | c.4463C>G p.P1488R | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52116625, COSV52132987, COSV52135343; called by muse, mutect2, varscan2
- CTNND2 | c.2665C>T p.R889* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV58884453; called by muse, mutect2, varscan2
- CYP2C9 | c.1084C>T p.L362F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV53250793; called by muse, varscan2
- DCTN1 | c.3481C>G p.Q1161E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV62619619, COSV62620999; called by muse, mutect2, varscan2
- DDC | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV63563651; called by muse, mutect2, varscan2
- DIAPH1 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53885651; called by muse, mutect2, varscan2
- DMPK | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs778669160, COSV52180219; called by muse, mutect2, varscan2
- DMRT1 | c.679A>T p.N227Y | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66522903; called by muse, mutect2
- DNAH9 | c.5110G>A p.E1704K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV52362699; called by muse, mutect2, varscan2
- DOT1L | c.4227G>T p.K1409N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.553); catalogued as COSV67111737; called by muse, mutect2
- DSEL | c.2815G>A p.D939N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV59491052, COSV59493251; called by muse, mutect2, varscan2
- DST | c.22238C>T p.S7413F (on ENST00000361203 / NM_001374722.1; = p.S5123F on NM_015548.5) | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54998630; called by muse, mutect2, varscan2
- EBF3 | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV100799183; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs763136855, COSV62567064; called by muse, mutect2, varscan2
- ELANE | c.464G>C p.G155A | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55048640; called by muse, mutect2, varscan2
- EPHA5 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.373); catalogued as rs867811974, COSV56632676, COSV56655183; called by muse, mutect2, varscan2
- EPSTI1 | c.750G>C p.K250N (on ENST00000398762 / NM_001330543.2; = p.K239N on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV58047183; called by muse, mutect2, varscan2
- ETF1 | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV62127778; called by muse, mutect2, varscan2
- FBXO40 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV100573268, COSV57525926; called by muse, mutect2, varscan2
- FDFT1 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs779354465, COSV55041494; called by muse, mutect2, varscan2
- FHDC1 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV52601583; called by muse, mutect2
- FLII | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs756056693, COSV58946458; called by muse, mutect2, varscan2
- FREM2 | c.2267C>A p.A756D | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV54844627; called by muse, mutect2, varscan2
- FRG2C | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.771); catalogued as rs1470355880; called by muse, mutect2, varscan2
- GCG | c.187A>C p.S63R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV64961824; called by muse, mutect2, varscan2
- GGA2 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59169575; called by muse, mutect2, varscan2
- GLI1 | c.2251C>G p.L751V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV57364860, COSV99953633; called by muse, mutect2, varscan2
- GOLGB1 | c.8557G>C p.E2853Q | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.259); catalogued as rs1220639767, COSV61468302; called by muse, mutect2, varscan2
- GRAMD2A | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59034175; called by muse, mutect2, varscan2
- H2BC21 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.404); catalogued as COSV100479607, COSV58611455; called by muse, mutect2, varscan2
- HERPUD1 | c.916G>T p.G306W | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55862839; called by muse, mutect2, varscan2
- HLA-DMB | c.336A>T p.T112= | Splice Region (SNP) | VAF 42/191 reads (22%) | catalogued as COSV101186828; called by muse, mutect2, varscan2
- IFNA5 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as COSV52386954, COSV52387268; called by muse, mutect2, varscan2
- IL4R | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs756023095, COSV50155102; called by muse, mutect2, varscan2
- ITGA2 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56863432; called by muse, mutect2, varscan2
- ITGA4 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52002169; called by muse, mutect2, varscan2
- ITIH3 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV56256836; called by muse, mutect2, varscan2
- ITPRID1 | c.2836C>T p.L946F | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV60078606; called by muse, mutect2, varscan2
- KCNK9 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs753123156, COSV57279105; called by muse, mutect2, varscan2
- KDM5A | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV66994567; called by muse, mutect2, varscan2
- KIF24 | c.1460G>C p.R487P | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61456813; called by muse, mutect2, varscan2
- KLC2 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 49/75 reads (65%) | catalogued as COSV100385267, COSV57582504, COSV57583573; called by muse, mutect2, varscan2
- LAMTOR4 | c.49G>C p.G17R | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57587220; called by muse, mutect2, varscan2
- LRP1B | c.7435T>C p.C2479R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67249708; called by muse, mutect2
- LRRC31 | c.990G>A p.L330= | Splice Region (SNP) | VAF 7/103 reads (7%) | catalogued as rs1398066061, COSV52980513, COSV99246569; called by muse, mutect2
- LRRC37A3 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs1374972943, COSV58536067; called by muse, mutect2, varscan2
- LYZL2 | c.19A>G p.S7G | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.115); catalogued as COSV64684669; called by muse, varscan2
- MAPK8 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1162940624, COSV64410205; called by muse, mutect2, varscan2
- MOCS1 | c.705G>C p.L235F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.12); catalogued as COSV57938157; called by muse, mutect2, varscan2
- MYH2 | c.5506C>G p.Q1836E | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.644); catalogued as COSV55443335; called by muse, mutect2, varscan2
- NEFM | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV55333717; called by muse, mutect2
- NLRP10 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as rs1331788860, COSV60781292; called by muse, mutect2, varscan2
- NOTCH2 | c.6892C>T p.R2298W | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1270274564, COSV56685860; called by muse, mutect2, varscan2
- OR2A14 | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs763848086, COSV101376461; called by muse, mutect2
- OR2C1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144009681, COSV59240731; called by muse, mutect2, varscan2
- OR2T27 | c.434T>A p.V145E | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV61280995, COSV61282877; called by mutect2, varscan2
- OR5AC2 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs762958470, COSV62279828, COSV62280302; called by muse, mutect2, varscan2
- PABPN1L | c.668G>C p.R223T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs775977916, COSV104396143, COSV56352178; called by muse, mutect2, varscan2
- PCDHA5 | c.778G>T p.V260F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV65354681; called by muse, mutect2
- PCDHB11 | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV99504235; called by muse, mutect2
- PCDHGA10 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as rs778441176, COSV53989655; called by muse, mutect2, varscan2
- PCSK4 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777976321, COSV52014276; called by muse, mutect2, varscan2
- PKD1 | c.7919C>T p.A2640V | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs141175694; called by muse, mutect2, varscan2
- PKNOX2 | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV53549581; called by muse, mutect2, varscan2
- PLCH1 | c.3482C>G p.S1161C (on ENST00000340059 / NM_001130960.2; = p.S1153C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.395); catalogued as rs769687200, COSV100397226, COSV58204473; called by muse, mutect2, varscan2
- PLIN4 | c.1418G>T p.G473V (on ENST00000301286; = p.G488V on NM_001367868.2) | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773765267, COSV56694668; called by muse, mutect2, varscan2
- PPL | c.2445G>C p.E815D | Missense Mutation (SNP) | VAF 63/101 reads (62%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV62048874; called by muse, mutect2, varscan2
- PPP1R16B | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55380731; called by muse, mutect2, varscan2
- PPP3CC | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV51502308; called by muse, mutect2, varscan2
- PRPF8 | c.5248G>C p.G1750R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV59265489; called by muse, mutect2, varscan2
- PRUNE2 | c.8725G>T p.G2909* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV56318019; called by muse, mutect2, varscan2
- PTPRD | c.3653A>G p.Q1218R | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV61964737; called by muse, mutect2, varscan2
- RAD21 | c.145-1G>A p.X49_splice | Splice Site (SNP) | VAF 18/74 reads (24%) | catalogued as COSV52061484; called by muse, mutect2, varscan2
- RASGRF2 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs764765268, COSV54134523; called by muse, mutect2, varscan2
- RASIP1 | c.2553G>A p.W851* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as COSV55806660; called by muse, mutect2, varscan2
- RBPJL | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV59214965; called by muse, mutect2, varscan2
- SCNN1A | c.1124C>A p.T375N | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV57436581; called by muse, mutect2, varscan2
- SERPINA7 | c.1219G>T p.G407W | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59666610; called by muse, mutect2, varscan2
- SLC32A1 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV54146583; called by muse, mutect2, varscan2
- SLC4A3 | c.3658G>A p.D1220N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV56095848; called by muse, mutect2, varscan2
- SMARCAD1 | c.2182C>G p.L728V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62775394; called by muse, mutect2, varscan2
- SNAP91 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 87/149 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs755782426, COSV52128480; called by muse, mutect2, varscan2
- SPINT2 | c.553+1G>T p.X185_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV56648438; called by muse, mutect2, varscan2
- SPNS3 | c.1196G>C p.R399T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61071086; called by muse, mutect2, varscan2
- SRSF12 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV71683733; called by muse, mutect2, varscan2
- STXBP5L | c.1969G>C p.G657R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56524278; called by muse, mutect2, varscan2
- STXBP5L | c.3070G>A p.D1024N | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV56524288; called by muse, mutect2, varscan2
- STYK1 | c.452-1G>A p.X151_splice | Splice Site (SNP) | VAF 38/70 reads (54%) | catalogued as COSV50014180; called by muse, mutect2, varscan2
- SURF1 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.248); catalogued as COSV100034677; called by muse, mutect2
- SYT11 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV64175510; called by muse, mutect2, varscan2
- TBC1D21 | c.54C>A p.F18L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.095); catalogued as COSV55996013; called by muse, mutect2, varscan2
- TBC1D22B | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 58/91 reads (64%) | catalogued as COSV65143133; called by muse, mutect2, varscan2
- TCF3 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756584024, COSV53651464; called by muse, mutect2, varscan2
- TIGD6 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs753968631, COSV57061432; called by muse, mutect2, varscan2
- TMEM45A | c.414C>G p.F138L | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV60254720; called by muse, mutect2, varscan2
- TMPRSS15 | c.176G>C p.R59T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.052); catalogued as COSV53044065; called by muse, mutect2, varscan2
- TNFRSF1A | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.902); catalogued as rs201794033, COSV50605394; called by muse, mutect2
- TPO | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs147325430, COSV61098181; called by muse, mutect2, varscan2
- TRMT1L | c.1702G>C p.E568Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as COSV62272083; called by muse, mutect2, varscan2
- TRNAU1AP | c.581A>C p.N194T | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV65778196; called by muse, mutect2, varscan2
- TTC16 | c.2528C>G p.S843* | Nonsense Mutation (SNP) | VAF 19/30 reads (63%) | catalogued as COSV60161592; called by muse, mutect2, varscan2
- TTN | c.54863C>A p.A18288D (on ENST00000591111; = p.A10864D on NM_003319.4) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | PolyPhen benign (0.031); catalogued as COSV60199732; called by muse, mutect2, varscan2
- TTN | c.19403C>T p.S6468L (on ENST00000591111; = p.S5541L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | PolyPhen benign (0.001); catalogued as rs201586695, COSV60195448; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TXNDC2 | c.354C>G p.D118E (on ENST00000306084 / NM_001098529.2; = p.D51E on NM_032243.6) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV60154487; called by muse, mutect2, varscan2
- UBE2I | c.309G>C p.W103C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57647701; called by muse, mutect2, varscan2
- UROC1 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 16/138 reads (12%) | catalogued as COSV52030916, COSV52036118; called by muse, mutect2, varscan2
- UVRAG | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV62107205; called by muse, mutect2, varscan2
- VAV1 | c.366G>C p.Q122H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV58387695; called by muse, mutect2, varscan2
- VPS4B | c.1293G>T p.L431F | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV53069870, COSV53070136; called by muse, mutect2, varscan2
- VWA3A | c.2817G>C p.Q939H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV55393323; called by muse, mutect2, varscan2
- WDFY3 | c.9608T>C p.V3203A | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55708415; called by muse, mutect2, varscan2
- WDR45B | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs780142007, COSV66408824; called by muse, mutect2, varscan2
- WFIKKN2 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156711172, COSV60959520; called by muse, mutect2, varscan2
- WNT11 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59444400; called by muse, mutect2, varscan2
- YBX1 | c.725G>C p.R242T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV100172093, COSV58438353; called by muse, mutect2
- ZNF557 | c.320C>T p.P107L (on ENST00000414706 / NM_001044388.2; = p.P114L on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV53274494; called by muse, mutect2, varscan2
- ZNF638 | c.3500T>C p.L1167P | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as rs763709853, COSV52491881; called by muse, mutect2
- ZNF70 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs1487312633, COSV100558879; called by muse, mutect2
- CRBN | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSGALNACT2 | c.909_916dup p.T306Ifs*20 | Frame Shift Ins (INS) | VAF 14/52 reads (27%) | called by mutect2, varscan2
- CYP2C9 | c.1130_1141del p.R377_L380del | In Frame Del (DEL) | VAF 9/51 reads (18%) | called by pindel, varscan2
- MRC1 | c.4007A>T p.H1336L | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T33 | c.842del p.P281Lfs*3 | Frame Shift Del (DEL) | VAF 14/107 reads (13%) | called by mutect2, varscan2
- PARP14 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- PCLO | c.2726_2762del p.L909Qfs*7 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel
- RMI1 | c.1742G>T p.C581F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEMA4C | c.2339del p.G780Vfs*15 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | called by mutect2, pindel, varscan2
- TBX18 | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- ZNF605 | c.1128A>T p.R376S | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AADAC | c.114A>G p.A38= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV51760424; called by muse, mutect2, varscan2
- AC008397.2 | c.1698C>T p.A566= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs373284282, COSV99441888; called by muse, mutect2, varscan2
- AMPD2 | c.1890G>A p.L630= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV56646281, COSV99857683; called by muse, mutect2, varscan2
- ASB15 | c.615G>A p.L205= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs1161364278, COSV51927741; called by muse, mutect2, varscan2
- BIN3 | c.723C>T p.L241= | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as COSV52385648; called by muse, mutect2, varscan2
- CHRM3 | c.576T>A p.A192= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as COSV55095749; called by muse, mutect2, varscan2
- CNOT6L | c.1161G>A p.E387= (on ENST00000504123 / NM_001286790.2; = p.E382= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99361785; called by muse, mutect2, varscan2
- COASY | c.1008C>T p.F336= | Silent (SNP) | VAF 30/44 reads (68%) | catalogued as COSV55899625; called by muse, mutect2, varscan2
- DNAJB12 | c.525G>A p.K175= (on ENST00000338820; = p.K141= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV58761052; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1206G>C p.L402= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV62569333; called by muse, mutect2, varscan2
- EYA2 | c.78C>T p.D26= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs141069620; called by muse, mutect2, varscan2
- FBXO32 | c.510C>G p.L170= | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as COSV99785907; called by muse, mutect2
- FERMT1 | c.840G>A p.L280= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV54095354; called by muse, mutect2, varscan2
- FLT3 | c.1659C>A p.L553= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV54061706; called by muse, varscan2
- GBP5 | c.942C>T p.V314= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs1294623515, COSV100600033, COSV58593655; called by muse, mutect2, varscan2
- IGKV3D-11 | c.234C>A p.I78= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- ITGB6 | c.1962G>A p.A654= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs201818641, COSV51796580; called by muse, mutect2, varscan2
- LRRIQ4 | c.747C>T p.I249= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV61619698; called by muse, mutect2, varscan2
- MIEN1 | c.339C>A p.V113= | Silent (SNP) | VAF 56/84 reads (67%) | catalogued as COSV54076573; called by muse, mutect2, varscan2
- MTUS2 | c.2949G>A p.P983= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs200073929, COSV70923612; called by muse, mutect2, varscan2
- MYO10 | c.2319G>A p.Q773= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as rs1343480460, COSV57025813; called by muse, mutect2, varscan2
- MYO15A | c.6888C>T p.F2296= | Silent (SNP) | VAF 59/88 reads (67%) | catalogued as COSV52761066; called by muse, mutect2, varscan2
- MYO1F | c.2871G>T p.G957= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV57797792; called by muse, mutect2, varscan2
- MYO3A | c.4827C>A p.R1609= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV52163069, COSV99393944; called by muse, mutect2, varscan2
- NCF1 | c.1032G>A p.Q344= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV56876268; called by mutect2, varscan2
- NLRC4 | c.1815T>C p.C605= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV61593861; called by muse, mutect2, varscan2
- NRSN1 | c.393A>T p.A131= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV65894275; called by mutect2, varscan2
- NT5E | c.420G>A p.L140= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV57629418; called by muse, mutect2, varscan2
- PCF11 | c.783T>A p.I261= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV53535048; called by muse, mutect2, varscan2
- PGBD2 | c.1575G>A p.L525= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1218371955, COSV61400630; called by muse, mutect2, varscan2
- PKD1 | c.5286C>A p.T1762= | Silent (SNP) | VAF 41/192 reads (21%) | catalogued as COSV51920847; called by muse, mutect2, varscan2
- RASGEF1C | c.978C>T p.F326= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV63182667; called by muse, mutect2, varscan2
- RNF128 | c.309G>A p.T103= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs1372589664, COSV55252887, COSV99718274; called by muse, mutect2, varscan2
- RTKN2 | c.1659G>A p.Q553= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV59523357; called by muse, mutect2, varscan2
- SCARB1 | c.432G>T p.A144= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV55550181; called by muse, mutect2, varscan2
- SLC39A3 | c.423G>A p.A141= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs938541300, COSV54118570; called by muse, mutect2, varscan2
- ST3GAL3 | c.711C>T p.R237= (on ENST00000361392 / NM_174964.4; = p.R222= on NM_006279.5) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs773310944, COSV99495327; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ST8SIA4 | c.147C>G p.V49= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV51513227; called by muse, mutect2, varscan2
- STIL | c.2844A>T p.L948= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV54551995; called by muse, mutect2
- SYDE1 | c.1425C>G p.L475= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV54619466, COSV54621054; called by muse, varscan2
- THSD7B | c.4083G>A p.L1361= (on ENST00000272643; = p.L1359= on NM_001316349.2) | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs1190436106, COSV55713302; called by muse, mutect2, varscan2
- TMEM151A | c.807G>A p.S269= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV59174396; called by muse, mutect2, varscan2
- UACA | c.3513G>A p.Q1171= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV59857752; called by muse, mutect2, varscan2
- UHRF1 | c.1383C>A p.V461= (on ENST00000612630 / NM_001290050.1; = p.V474= on NM_013282.4) | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as COSV53575756; called by muse, mutect2, varscan2
- ZEB2 | c.2871G>A p.R957= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV100355963; called by muse, mutect2, varscan2
- ZNF324B | c.993C>T p.H331= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV60742603; called by muse, mutect2, varscan2
- ZNF544 | c.1821C>T p.N607= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs749212514, COSV99517004; called by muse, mutect2, varscan2
- ZNF816 | c.705C>G p.G235= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV54411849; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73826119 G>T | 5'Flank (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.*1806G>A | 3'UTR (SNP) | VAF 25/130 reads (19%) | catalogued as rs146389619; called by muse, mutect2, varscan2
- DPH6 | c.312+16041C>T | Intron (SNP) | VAF 10/23 reads (43%) | catalogued as COSV56616854; called by muse, mutect2, varscan2
- FAM13B | c.1442-2119C>T | Intron (SNP) | VAF 14/46 reads (30%) | catalogued as COSV50369423; called by muse, mutect2, varscan2
- MDS2 | n.82T>G | RNA (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- SSX9P | n.384G>C | RNA (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
- SYTL2 | c.1460-3385G>A | Intron (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100314596, COSV60361187; called by muse, mutect2, varscan2
- ZNF658B | n.2520A>T | RNA (SNP) | VAF 32/132 reads (24%) | called by muse, varscan2
